Somatic mutation profile of tumor specimen MMRF_1825_1_BM_CD138pos (aliquot MMRF_1825_1_BM_CD138pos_T1_KBS5U_K11335) from MMRF case MMRF_1825, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 55.0 years (20,074 days).
Specimen MMRF_1825_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1beb8b50-9c40-4422-9776-00ac48bd56d6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1825_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1825_1_PB_Whole_C2_KBS5U_K11336; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/55ba1e44-7669-4cfb-8c62-49773a3c0d72

The open-access MAF lists 113 somatic variants for this specimen: 43 protein-altering or splice-affecting, 15 silent, 55 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 37, 3'UTR 34, Silent 15, Intron 11, 5'UTR 6, Frame Shift Del 3, RNA 2, 3'Flank 2, Splice Site 1, Nonstop Mutation 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARHGEF6 | c.284A>C p.N95T | Missense Mutation (SNP) | VAF 67/67 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.922); catalogued as COSV51692081; called by muse, mutect2, varscan2
- CDH7 | c.791G>A p.R264Q | Missense Mutation (SNP) | VAF 67/125 reads (54%) | SIFT tolerated (1); PolyPhen benign (0.357); catalogued as rs767686297, COSV59883221; called by muse, mutect2, varscan2
- COLGALT1 | c.1412G>A p.R471Q | Missense Mutation (SNP) | VAF 86/121 reads (71%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.978); catalogued as rs1297678804; called by muse, mutect2, varscan2
- FAT3 | c.3569G>A p.G1190E | Missense Mutation (SNP) | VAF 38/125 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1361953695, COSV99967813; called by muse, mutect2, varscan2
- FCAMR | c.1406C>T p.P469L | Missense Mutation (SNP) | VAF 22/36 reads (61%) | SIFT tolerated (0.55); PolyPhen benign (0.026); catalogued as rs565462436; called by muse, mutect2, varscan2
- FSIP2 | c.4737A>C p.K1579N | Missense Mutation (SNP) | VAF 55/92 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1198169695; called by muse, mutect2, varscan2
- H1-5 | c.275G>A p.S92N | Missense Mutation (SNP) | VAF 53/176 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.238); catalogued as rs1210490306; called by muse, mutect2, varscan2
- HSPA1B | c.1864T>G p.F622V | Missense Mutation (SNP) | VAF 8/124 reads (6%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.011); catalogued as rs762557780; called by muse, mutect2
- IGLV3-16 | c.146A>T p.K49I | Missense Mutation (SNP) | VAF 55/59 reads (93%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as rs545033113; called by muse, mutect2, varscan2
- IGLV3-19 | c.144C>G p.S48R | Missense Mutation (SNP) | VAF 13/15 reads (87%) | SIFT tolerated (0.27); PolyPhen benign (0.009); catalogued as rs372995146; called by muse, mutect2, varscan2
- IGLV4-60 | c.153C>G p.S51R | Missense Mutation (SNP) | VAF 67/152 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.047); catalogued as rs191540570; called by muse, mutect2, varscan2
- JAKMIP2 | c.30G>C p.E10D | Missense Mutation (SNP) | VAF 117/119 reads (98%) | SIFT tolerated (0.5); PolyPhen benign (0.006); catalogued as COSV99508167; called by muse, mutect2, varscan2
- PCNX2 | c.313G>A p.D105N | Missense Mutation (SNP) | VAF 41/158 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV50808407; called by muse, mutect2, varscan2
- PITRM1 | c.697G>A p.V233M | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs375511163; called by muse, mutect2, varscan2
- PSMG3 | c.332C>T p.A111V | Missense Mutation (SNP) | VAF 9/104 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.166); catalogued as rs372483327; called by muse, mutect2
- RBMS3 | c.792-1G>A p.X264_splice | Splice Site (SNP) | VAF 68/242 reads (28%) | catalogued as COSV99822061; called by muse, mutect2, varscan2
- THSD4 | c.1844G>A p.R615H | Missense Mutation (SNP) | VAF 131/386 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.719); catalogued as rs369839470; called by muse, mutect2, varscan2
- TTC7B | c.792G>T p.Q264H | Missense Mutation (SNP) | VAF 37/81 reads (46%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.965); catalogued as rs746508536; called by muse, mutect2, varscan2
- ZNF716 | c.728G>A p.C243Y | Missense Mutation (SNP) | VAF 31/63 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV101348655; called by muse, mutect2, varscan2
- ADRA1B | c.1192G>T p.E398* | Nonsense Mutation (SNP) | VAF 4/12 reads (33%) | called by muse, mutect2, varscan2
- ATP6V1B1 | c.1291G>A p.A431T | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- C5AR1 | c.445G>A p.G149R | Missense Mutation (SNP) | VAF 60/131 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- CEP135 | c.1775T>C p.L592S | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- FUBP1 | c.710T>A p.I237N | Missense Mutation (SNP) | VAF 31/271 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IGHV2-70D | c.79G>T p.G27C | Missense Mutation (SNP) | VAF 41/42 reads (98%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, varscan2
- KLF3 | c.1036T>G p.*346Gext*9 | Nonstop Mutation (SNP) | VAF 47/762 reads (6%) | called by muse, mutect2
- MGME1 | c.864G>T p.Q288H | Missense Mutation (SNP) | VAF 51/108 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- MUC3A | c.9789del p.W3264Gfs*46 | Frame Shift Del (DEL) | VAF 42/197 reads (21%) | called by mutect2, pindel, varscan2
- NUP210 | c.2964G>T p.K988N | Missense Mutation (SNP) | VAF 39/56 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PCDHA3 | c.1051G>A p.V351I | Missense Mutation (SNP) | VAF 212/216 reads (98%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- PSMF1 | c.205T>G p.Y69D | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ROCK1 | c.3226C>A p.L1076I | Missense Mutation (SNP) | VAF 76/194 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- RUBCN | c.187_200del p.S63Rfs*5 | Frame Shift Del (DEL) | VAF 29/100 reads (29%) | called by mutect2, pindel, varscan2
- SCN5A | c.2915_2951del p.F972Sfs*161 (on ENST00000333535 / NM_198056.3; = p.F972Sfs*160 on NM_000335.5) | Frame Shift Del (DEL) | VAF 10/70 reads (14%) | called by mutect2, pindel
- SETD2 | c.6013A>T p.I2005L | Missense Mutation (SNP) | VAF 31/117 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- SNAP91 | c.556A>C p.N186H | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- TNC | c.1397G>T p.S466I | Missense Mutation (SNP) | VAF 10/207 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.498); called by muse, mutect2
- UBXN6 | c.581A>G p.Y194C | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UNC80 | c.542C>G p.S181C | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.723); called by muse, mutect2, varscan2
- USF3 | c.2308G>C p.A770P | Missense Mutation (SNP) | VAF 96/159 reads (60%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZDBF2 | c.3670T>C p.W1224R | Missense Mutation (SNP) | VAF 16/252 reads (6%) | SIFT tolerated (0.3); PolyPhen benign (0.035); called by muse, mutect2
- ZNF415 | c.154G>A p.V52I | Missense Mutation (SNP) | VAF 9/129 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.007); called by muse, mutect2
- ZNF445 | c.2605A>G p.K869E | Missense Mutation (SNP) | VAF 95/165 reads (58%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- ADAM30 | c.267C>T p.R89= | Silent (SNP) | VAF 29/90 reads (32%) | catalogued as rs767005904, COSV65560297; called by muse, mutect2, varscan2
- ARNT2 | c.2121C>T p.A707= | Silent (SNP) | VAF 112/173 reads (65%) | catalogued as rs76517462; called by muse, mutect2, varscan2
- BEND2 | c.1581T>C p.H527= | Silent (SNP) | VAF 60/61 reads (98%) | catalogued as rs1377319600; called by muse, varscan2
- DOCK3 | c.3669G>T p.L1223= | Silent (SNP) | VAF 14/164 reads (9%) | catalogued as rs1291236931; called by muse, mutect2
- FEZF2 | c.48G>A p.P16= | Silent (SNP) | VAF 21/85 reads (25%) | catalogued as rs1410978295, COSV51862514; called by muse, mutect2, varscan2
- IGHV2-70 | c.339G>A p.T113= | Silent (SNP) | VAF 37/56 reads (66%) | catalogued as rs376111067; called by muse, varscan2
- IGHV2-70 | c.57C>G p.S19= | Silent (SNP) | VAF 43/121 reads (36%) | catalogued as rs554480066; called by muse, mutect2, varscan2
- NSUN6 | c.414A>C p.A138= | Silent (SNP) | VAF 12/182 reads (7%) | called by muse, mutect2
- PHF10 | c.600T>C p.I200= | Silent (SNP) | VAF 16/36 reads (44%) | called by muse, mutect2, varscan2
- PHYKPL | c.189C>T p.C63= | Silent (SNP) | VAF 3/47 reads (6%) | called by muse, mutect2
- SLC27A5 | c.1599C>T p.T533= | Silent (SNP) | VAF 12/204 reads (6%) | called by muse, mutect2
- SLITRK4 | c.135G>A p.K45= | Silent (SNP) | VAF 8/50 reads (16%) | called by muse, mutect2, varscan2
- SPTBN5 | c.10776G>A p.T3592= | Silent (SNP) | VAF 48/258 reads (19%) | catalogued as rs372260288, COSV100312236; called by muse, mutect2, varscan2
- TMSB4X | c.69G>A p.T23= | Silent (SNP) | VAF 34/37 reads (92%) | catalogued as COSV66081143; called by muse, mutect2, varscan2
- ZFP57 | c.192C>T p.S64= | Silent (SNP) | VAF 14/52 reads (27%) | catalogued as rs779376984; called by muse, mutect2, varscan2
- ABTB2 | c.-248G>A | 5'UTR (SNP) | VAF 70/105 reads (67%) | catalogued as rs550430624; called by muse, mutect2, varscan2
- AC018755.3 | chr19:51601721 C>G | 3'Flank (SNP) | VAF 39/149 reads (26%) | called by muse, mutect2, varscan2
- ALAS1 | c.*49A>G | 3'UTR (SNP) | VAF 54/186 reads (29%) | catalogued as rs1005444899; called by muse, mutect2, varscan2
- ALDH9A1 | c.-122G>A | 5'UTR (SNP) | VAF 42/68 reads (62%) | called by muse, varscan2
- AP3S2 | c.70-16T>G | Intron (SNP) | VAF 26/117 reads (22%) | called by muse, mutect2, varscan2
- ARHGEF7 | c.*1207G>A | 3'UTR (SNP) | VAF 3/21 reads (14%) | called by muse, mutect2
- ASB5 | c.*1218A>T | 3'UTR (SNP) | VAF 6/116 reads (5%) | called by muse, mutect2
- B3GALT5-AS1 | n.744C>T | RNA (SNP) | VAF 70/188 reads (37%) | called by muse, mutect2, varscan2
- BCL7A | c.-14T>C | 5'UTR (SNP) | VAF 12/20 reads (60%) | catalogued as rs1029075366; called by muse, mutect2, varscan2
- BMP6 | c.*1177dup | 3'UTR (INS) | VAF 27/149 reads (18%) | catalogued as rs201060827; called by mutect2, pindel, varscan2
- CAMK2B | c.415-1483C>T | Intron (SNP) | VAF 49/102 reads (48%) | catalogued as rs778649589; called by muse, mutect2, varscan2
- CLMN | c.241-784G>A | Intron (SNP) | VAF 8/24 reads (33%) | catalogued as rs1192399548; called by muse, mutect2
- CNOT6 | c.*3984C>T | 3'UTR (SNP) | VAF 51/53 reads (96%) | called by muse, mutect2, varscan2
- DDRGK1 | c.730-136G>T | Intron (SNP) | VAF 29/98 reads (30%) | called by muse, mutect2, varscan2
- DUSP8 | c.*1431G>T | 3'UTR (SNP) | VAF 20/60 reads (33%) | called by muse, mutect2
- EGR1 | c.-61G>A | 5'UTR (SNP) | VAF 22/22 reads (100%) | catalogued as COSV53517796; called by muse, mutect2, varscan2
- FAM13A | c.2844-83A>G | Intron (SNP) | VAF 18/92 reads (20%) | called by muse, mutect2, varscan2
- GABRB2 | c.*5380A>T | 3'UTR (SNP) | VAF 88/92 reads (96%) | called by muse, varscan2
- GABRB2 | c.*5266A>C | 3'UTR (SNP) | VAF 96/102 reads (94%) | called by muse, varscan2
- GRAMD1B | c.-158C>A | 5'UTR (SNP) | VAF 46/212 reads (22%) | called by muse, mutect2, varscan2
- GRIN2A | c.*3244G>A | 3'UTR (SNP) | VAF 32/56 reads (57%) | called by muse, mutect2, varscan2
- HAVCR1 | c.*87A>C | 3'UTR (SNP) | VAF 111/371 reads (30%) | called by muse, mutect2, varscan2
- KCTD16 | c.*1317T>C | 3'UTR (SNP) | VAF 70/72 reads (97%) | called by muse, mutect2, varscan2
- KMT5B | c.*717C>A | 3'UTR (SNP) | VAF 26/87 reads (30%) | catalogued as rs1327375539; called by muse, mutect2, varscan2
- LEPROTL1 | c.*2649T>G | 3'UTR (SNP) | VAF 44/76 reads (58%) | called by muse, mutect2, varscan2
- MIR1270 | chr19:20397508 C>A | 3'Flank (SNP) | VAF 10/206 reads (5%) | called by muse, mutect2
- NADK2 | c.*809T>C | 3'UTR (SNP) | VAF 77/79 reads (97%) | called by muse, mutect2, varscan2
- NDOR1 | c.*87G>A | 3'UTR (SNP) | VAF 3/41 reads (7%) | catalogued as rs948650727; called by muse, mutect2
- NPM1 | c.139-170T>C | Intron (SNP) | VAF 22/58 reads (38%) | called by muse, mutect2, varscan2
- NSD2 | c.1881+2721A>G | Intron (SNP) | VAF 9/124 reads (7%) | called by muse, mutect2
- PCBP3 | c.*626C>T | 3'UTR (SNP) | VAF 17/43 reads (40%) | called by muse, mutect2
- PDGFA | c.*244T>C | 3'UTR (SNP) | VAF 23/43 reads (53%) | called by muse, mutect2, varscan2
- PHACTR2 | c.*186G>A | 3'UTR (SNP) | VAF 25/139 reads (18%) | called by muse, mutect2, varscan2
- PLP1 | c.*616G>A | 3'UTR (SNP) | VAF 52/85 reads (61%) | called by muse, mutect2, varscan2
- QKI | c.*80C>A | 3'UTR (SNP) | VAF 368/600 reads (61%) | called by muse, mutect2, varscan2
- RANBP2 | c.*1031T>A | 3'UTR (SNP) | VAF 42/99 reads (42%) | called by muse, mutect2, varscan2
- RBM24 | c.348-1726C>T | Intron (SNP) | VAF 53/162 reads (33%) | catalogued as rs868232470; called by muse, mutect2, varscan2
- RGS13 | c.66-47C>T | Intron (SNP) | VAF 10/44 reads (23%) | called by muse, varscan2
- SLC26A2 | c.*1930T>A | 3'UTR (SNP) | VAF 23/49 reads (47%) | called by muse, mutect2, varscan2
- SLC5A3 | c.*7065G>A | 3'UTR (SNP) | VAF 58/107 reads (54%) | catalogued as COSV62967497; called by muse, mutect2, varscan2
- SLC7A2 | c.*900G>A | 3'UTR (SNP) | VAF 6/47 reads (13%) | called by muse, mutect2, varscan2
- SORBS2 | c.-50C>A | 5'UTR (SNP) | VAF 40/172 reads (23%) | called by muse, mutect2, varscan2
- SOX11 | c.*3470C>T | 3'UTR (SNP) | VAF 42/84 reads (50%) | catalogued as rs1356565874; called by muse, mutect2, varscan2
- STS | c.*3041G>A | 3'UTR (SNP) | VAF 21/30 reads (70%) | called by muse, mutect2, varscan2
- SYT7 | c.*293C>T | 3'UTR (SNP) | VAF 41/127 reads (32%) | called by muse, mutect2, varscan2
- TMED10 | c.*1537G>A | 3'UTR (SNP) | VAF 40/67 reads (60%) | called by muse, mutect2, varscan2
- VAMP4 | c.*1291A>G | 3'UTR (SNP) | VAF 23/73 reads (32%) | catalogued as rs1364220048; called by muse, mutect2, varscan2
- VASH1 | c.*1582C>T | 3'UTR (SNP) | VAF 5/47 reads (11%) | called by muse, mutect2
- WRN | c.*400G>A | 3'UTR (SNP) | VAF 14/42 reads (33%) | catalogued as rs1482449572; called by muse, mutect2, varscan2
- ZC3H12C | c.*1798G>A | 3'UTR (SNP) | VAF 68/104 reads (65%) | catalogued as rs76316149; called by muse, mutect2, varscan2
- ZMIZ1 | c.1230+143C>T | Intron (SNP) | VAF 19/30 reads (63%) | called by muse, mutect2
- ZNF286B | n.3344G>A | RNA (SNP) | VAF 17/95 reads (18%) | called by muse, mutect2, varscan2
- ZNF462 | c.6832+285G>A | Intron (SNP) | VAF 9/30 reads (30%) | called by muse, mutect2, varscan2
- ZNF681 | c.*2862A>T | 3'UTR (SNP) | VAF 23/71 reads (32%) | called by muse, mutect2, varscan2
- ZNF777 | c.*314_*315del | 3'UTR (DEL) | VAF 48/193 reads (25%) | called by pindel, varscan2
